Gene-level copy-number profile of tumor specimen TCGA-EJ-7218-01B from TCGA case TCGA-EJ-7218, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 71.7 years (26,181 days).
Specimen TCGA-EJ-7218-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.ad0b4a31-fbfc-4766-86c7-9f9110efbb64.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EJ-7218-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS (2 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4b91c4f7-f5d1-404c-829e-59cad33d4dad

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 100; copy number 1: 5,035; copy number 2: 54,631; copy number 3: 51.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EJ-7218-01B-11D-A32A-01): tumor purity 0.45, ploidy 1.95, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 100 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:118,766,965–122,887,691, 56 genes (within-gene range 0–1): LINC01956, EN1, MARCO, AC013457.1, C1QL2, RN7SL468P, STEAP3, STEAP3-AS1, C2orf76, DBI, TMEM37, SCTR, SCTR-AS1, CFAP221, TMEM177, RPL17P15, PTPN4, RPL27P7, EPB41L5, AC012363.1, Y_RNA, MTATP6P26, MTCO3P43, MTND3P10, MTND4LP14, MTND4P26, MTND5P28, TMEM185B, RALB, AC012363.2, INHBB, LINC01101, AC073257.2, AC073257.1, Y_RNA, AC018866.1, GLI2, AC017033.1, Y_RNA, AC067960.1, AC079988.1, TFCP2L1, RPS17P7, CLASP1, AC012447.1, RNU4ATAC, Y_RNA, NIFK-AS1, RPL12P15, AC018737.2, NPM1P32, NIFK, TSN, AC018737.1, LINC01823, AC011246.1.
- chr6:85,751,581–86,214,576, 8 genes: RNU4-72P, Y_RNA, AL450338.1, AL450338.2, RNU4-12P, RPL7P27, RAB1AP2, NDUFA5P9.
- chr6:86,897,118–87,891,869, 31 genes: AL157777.1, AL157777.2, HTR1E, RPL7P29, MTHFD2P2, AL138827.1, RN7SKP209, CGA, RCN1P1, AL139274.2, ZNF292, AL139274.1, GJB7, HSPD1P10, SMIM8, C6orf163, AL096817.1, CFAP206, AL049697.1, AL049697.2, AL049697.3, ST13P16, SLC35A1, RNU6-444P, RARS2, ORC3, AKIRIN2, AL133211.1, Y_RNA, RN7SL183P, AL590392.1.
- chr6:95,504,182–96,015,391, 5 genes (within-gene range 0–1): CYCSP17, MANEA-DT, MANEA, AL607077.1, AL034348.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2,655. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
